Somatic mutation profile of tumor specimen MMRF_2204_2_BM_CD138pos (aliquot MMRF_2204_2_BM_CD138pos_T1_KHS5U_L13764) from MMRF case MMRF_2204, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.6 years (30,186 days).
Specimen MMRF_2204_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcfefe08-d213-40ab-aac1-614c5d17a6ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2204_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2204_1_PB_Whole_C2_KHS5U_L08776; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e420a55-452f-4a84-8058-26552d725ba3

The open-access MAF lists 147 somatic variants for this specimen: 54 protein-altering or splice-affecting, 21 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 43, Silent 21, Intron 14, 5'UTR 6, Splice Region 3, 5'Flank 3, RNA 3, 3'Flank 3, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA3 | c.1810-4dup | Splice Region (INS) | VAF 6/26 reads (23%) | catalogued as rs756865767; called by mutect2, pindel
- C8G | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs759586476, COSV56403921; called by muse, mutect2, varscan2
- CA5A | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as rs139748303; called by muse, mutect2, varscan2
- CARS1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as COSV99542250; called by muse, mutect2, varscan2
- CCHCR1 | c.2077_2079del p.L693del | In Frame Del (DEL) | VAF 49/126 reads (39%) | catalogued as rs759345745; called by pindel, varscan2
- CCIN | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 109/163 reads (67%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373879432; called by muse, mutect2, varscan2
- DTL | c.1126-7C>T | Splice Region (SNP) | VAF 41/97 reads (42%) | catalogued as rs1415437845; called by mutect2, varscan2
- FREM2 | c.7820G>A p.G2607E | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV54846703; called by muse, mutect2
- GNL3 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs942036186; called by muse, mutect2
- GRAMD1B | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1453213746; called by muse, mutect2, varscan2
- IGHV1-24 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.488); catalogued as rs782376088; called by muse, mutect2, varscan2
- IGHV2-70D | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1456429000; called by muse, varscan2
- IGHV2-70D | c.230A>C p.D77A | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1466061529; called by muse, varscan2
- IGHV2-70D | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1292545219; called by muse, varscan2
- IGLV3-9 | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 76/90 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.301); catalogued as rs745621281; called by muse, varscan2
- IGLV3-9 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 116/125 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs757627231; called by muse, mutect2, varscan2
- KLHL6 | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.403); catalogued as rs749942087, COSV58067504; called by muse, mutect2, varscan2
- LYPD6 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1219327059; called by muse, mutect2, varscan2
- MASP1 | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV51461710; called by muse, mutect2, varscan2
- MICU3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.024); catalogued as COSV58849276; called by muse, mutect2, varscan2
- PRRC2B | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs767401649, COSV61942418; called by muse, mutect2, varscan2
- PUS7L | c.714_717del p.N238Kfs*27 | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | catalogued as rs780133979; called by pindel, varscan2
- RYR2 | c.6850G>T p.G2284C | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1358347233, COSV63710725; called by muse, mutect2
- SAMHD1 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV53430834; called by muse, mutect2, varscan2
- SERPINB3 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 111/208 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs111442409, COSV99379727; called by muse, mutect2, varscan2
- SLC8A1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 9/272 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs866533352, COSV60493498; called by muse, mutect2
- TGOLN2 | c.209C>A p.S70* | Nonsense Mutation (SNP) | VAF 158/319 reads (50%) | catalogued as COSV56406947; called by muse, mutect2, varscan2
- VAV2 | c.2354G>A p.C785Y | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as rs1456299174; called by muse, mutect2, varscan2
- ZNF568 | c.1782G>C p.K594N | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as rs971606843; called by muse, mutect2, varscan2
- AL441992.2 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CEP290 | c.4581G>A p.M1527I | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTTNBP2 | c.2373-2A>T p.X791_splice | Splice Site (SNP) | VAF 35/148 reads (24%) | called by muse, mutect2, varscan2
- DNAJC2 | c.1041dup p.A348Sfs*3 | Frame Shift Ins (INS) | VAF 28/161 reads (17%) | called by mutect2, pindel, varscan2
- DNM1 | c.1690A>G p.M564V | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- EVC | c.2474T>G p.L825R | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- FAM193A | c.712C>G p.H238D | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- FAM83F | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- FUT6 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 92/282 reads (33%) | called by muse, mutect2, varscan2
- GJA8 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- GOLM2 | c.1129G>T p.A377S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR174 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.224); called by muse, mutect2
- HGF | c.977G>C p.C326S | Missense Mutation (SNP) | VAF 113/168 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HMOX1 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IGHV1-69D | c.152A>C p.Y51S | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- IGHV2-70D | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.073); called by muse, varscan2
- ISLR2 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 90/197 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MACIR | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 71/329 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- PPP1R21 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP2R1A | c.810C>T p.L270= | Splice Region (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- SNAPC3 | c.401A>G p.K134R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- TMEM131L | c.1025C>G p.T342R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TSPAN32 | c.413C>A p.T138K | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TXNDC5 | c.1237_1258del p.G413Yfs*6 | Frame Shift Del (DEL) | VAF 32/98 reads (33%) | called by mutect2, pindel, varscan2
- ZNF638 | c.5676T>A p.D1892E | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- A2ML1 | c.4356C>T p.P1452= | Silent (SNP) | VAF 14/290 reads (5%) | catalogued as COSV55298292; called by muse, mutect2
- ATP2C1 | c.2004T>A p.V668= | Silent (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- BRINP3 | c.1311G>C p.A437= | Silent (SNP) | VAF 62/190 reads (33%) | catalogued as COSV66516749, COSV66537597, COSV66539665; called by muse, mutect2, varscan2
- C1orf112 | c.2008T>C p.L670= | Silent (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- DOCK1 | c.4143C>T p.A1381= | Silent (SNP) | VAF 82/191 reads (43%) | catalogued as rs771141839, COSV54737170; called by muse, mutect2, varscan2
- EZH1 | c.708C>T p.I236= | Silent (SNP) | VAF 23/205 reads (11%) | called by muse, mutect2, varscan2
- FGR | c.405T>G p.P135= | Silent (SNP) | VAF 59/185 reads (32%) | called by muse, mutect2, varscan2
- FILIP1L | c.1510C>A p.R504= (on ENST00000354552 / NM_182909.3; = p.R264= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- HAAO | c.729A>G p.G243= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs767026824; called by muse, mutect2, varscan2
- IGHV2-70D | c.354G>C p.R118= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, varscan2
- IGHV2-70D | c.339G>C p.T113= | Silent (SNP) | VAF 14/82 reads (17%) | called by muse, varscan2
- KLK15 | c.459C>T p.T153= | Silent (SNP) | VAF 98/185 reads (53%) | catalogued as rs1270808246, COSV56828489; called by muse, mutect2, varscan2
- OR9A4 | c.210C>T p.I70= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV101516546; called by muse, mutect2, varscan2
- PCDHA7 | c.1326C>T p.S442= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as rs782335275; called by muse, mutect2
- PLCXD3 | c.960C>T p.N320= | Silent (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- PLD5 | c.588A>G p.L196= (on ENST00000442594; = p.L134= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/237 reads (21%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1044C>T p.V348= | Silent (SNP) | VAF 67/228 reads (29%) | catalogued as rs773142135; called by muse, mutect2, varscan2
- PTPRM | c.1638C>T p.T546= | Silent (SNP) | VAF 87/201 reads (43%) | called by muse, mutect2, varscan2
- RNF144A | c.807C>T p.L269= | Silent (SNP) | VAF 42/72 reads (58%) | catalogued as rs747815989, COSV57985423; called by muse, mutect2, varscan2
- STOML3 | c.837C>T p.V279= | Silent (SNP) | VAF 16/22 reads (73%) | called by muse, mutect2, varscan2
- WASF3 | c.480C>T p.L160= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- ACSL6 | c.993+96C>A | Intron (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99733939; called by mutect2, varscan2
- ADAM23 | c.*627C>T | 3'UTR (SNP) | VAF 13/146 reads (9%) | catalogued as rs1189237989; called by muse, mutect2
- AMACR | c.*729C>A | 3'UTR (SNP) | VAF 118/411 reads (29%) | called by muse, mutect2, varscan2
- ARID1B | c.*730T>G | 3'UTR (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- ATMIN | c.462+19A>T | Intron (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021570 C>G | 5'Flank (SNP) | VAF 68/134 reads (51%) | catalogued as COSV55848051; called by muse, mutect2, varscan2
- CADM3 | c.*1668G>A | 3'UTR (SNP) | VAF 73/296 reads (25%) | called by muse, mutect2, varscan2
- CBX3 | c.*23T>C | 3'UTR (SNP) | VAF 9/49 reads (18%) | catalogued as rs776117134, COSV100522967; called by muse, mutect2
- CCDC149 | c.*425G>A | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- CDON | c.*4456G>T | 3'UTR (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- CEP57L1 | c.745-1383G>A | Intron (SNP) | VAF 13/60 reads (22%) | catalogued as rs1329205691; called by muse, mutect2, varscan2
- CLDN5 | c.*346C>T | 3'UTR (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- COL5A1 | c.*1647C>T | 3'UTR (SNP) | VAF 70/206 reads (34%) | catalogued as rs1020845061, COSV65672920; called by muse, mutect2, varscan2
- CUL5 | c.*1756C>G | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
- DAZAP2 | c.132+140T>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- DNAJC16 | c.*1070T>A | 3'UTR (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- ELL2 | c.*1348T>G | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- FAM186A | chr12:50326669 A>G | 3'Flank (SNP) | VAF 28/96 reads (29%) | catalogued as rs1565876556; called by muse, mutect2, varscan2
- FBLN5 | chr14:91869948 T>A | 3'Flank (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- FERMT1 | c.*1710C>T | 3'UTR (SNP) | VAF 34/50 reads (68%) | called by muse, mutect2, varscan2
- FGF14 | c.209-170701G>T | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- FKBP1C | c.*270T>C | 3'UTR (SNP) | VAF 143/288 reads (50%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+2847A>T | Intron (SNP) | VAF 30/66 reads (45%) | catalogued as rs1251722170; called by muse, mutect2, varscan2
- GIMAP5 | c.-6-113A>G | Intron (SNP) | VAF 61/91 reads (67%) | called by muse, mutect2, varscan2
- GPM6B | chrX:13771309 T>C | 3'Flank (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- HEBP2 | chr6:138403524 C>T | 5'Flank (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- IFNL1 | c.*126A>G | 3'UTR (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- IGLC2 | c.*105A>G | 3'UTR (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2, varscan2
- INHBA | c.*3976A>T | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- IST1 | c.892-621C>T | Intron (SNP) | VAF 118/255 reads (46%) | called by muse, mutect2, varscan2
- KLRB1 | c.*205A>G | 3'UTR (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- LHFPL2 | c.*2115C>G | 3'UTR (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- MINDY3 | c.-87C>T | 5'UTR (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- MIR1305 | n.71G>C | RNA (SNP) | VAF 14/33 reads (42%) | called by muse, varscan2
- MYOF | c.4437+70A>G | Intron (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- NBN | c.*1490_*1491del | 3'UTR (DEL) | VAF 94/202 reads (47%) | called by pindel, varscan2
- NRP1 | c.*905G>A | 3'UTR (SNP) | VAF 26/81 reads (32%) | catalogued as rs766947380; called by muse, mutect2, varscan2
- OR5G5P | n.339C>T | RNA (SNP) | VAF 10/209 reads (5%) | called by muse, mutect2
- OXTR | c.*161A>G | 3'UTR (SNP) | VAF 38/85 reads (45%) | catalogued as rs1310773914; called by muse, mutect2, varscan2
- PCNX1 | c.*5403G>T | 3'UTR (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- PFKFB4 | chr3:48561698 C>T | 5'Flank (SNP) | VAF 6/58 reads (10%) | catalogued as rs13088174; called by muse, mutect2
- PLXDC2 | c.-74G>A | 5'UTR (SNP) | VAF 34/72 reads (47%) | called by muse, varscan2
- POMT1 | c.*219G>A | 3'UTR (SNP) | VAF 73/112 reads (65%) | catalogued as rs993064797; called by muse, mutect2
- PROP1 | c.-24G>A | 5'UTR (SNP) | VAF 123/376 reads (33%) | called by muse, mutect2, varscan2
- PTH2R | c.*668C>T | 3'UTR (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- RERGL | c.-44T>A | 5'UTR (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- RGS1 | c.*416A>T | 3'UTR (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- RNPEP | c.*179C>T | 3'UTR (SNP) | VAF 40/157 reads (25%) | catalogued as rs1158608515; called by muse, mutect2, varscan2
- RPL12 | c.*41T>G | 3'UTR (SNP) | VAF 109/371 reads (29%) | called by muse, mutect2, varscan2
- SAMD10 | c.*1132G>A | 3'UTR (SNP) | VAF 61/420 reads (15%) | called by muse, mutect2
- SCUBE3 | c.*1913C>A | 3'UTR (SNP) | VAF 58/132 reads (44%) | called by muse, mutect2, varscan2
- SERPINI1 | c.*68A>C | 3'UTR (SNP) | VAF 87/171 reads (51%) | called by muse, mutect2, varscan2
- SLC28A3 | c.*1657G>A | 3'UTR (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.*994G>A | 3'UTR (SNP) | VAF 58/111 reads (52%) | called by muse, mutect2, varscan2
- SNX27 | c.*3889G>A | 3'UTR (SNP) | VAF 84/135 reads (62%) | called by muse, mutect2, varscan2
- SNX29P2 | n.494G>A | RNA (SNP) | VAF 104/441 reads (24%) | called by muse, mutect2, varscan2
- SSBP2 | c.*1159C>T | 3'UTR (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- STXBP6 | c.-23G>A | 5'UTR (SNP) | VAF 15/207 reads (7%) | catalogued as rs139809980, COSV100121590; called by muse, mutect2
- TCEA1 | c.897+9T>A | Intron (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- TERB1 | c.*10G>T | 3'UTR (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- TGM2 | c.*18C>T | 3'UTR (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- TMCC2 | c.*1069C>A | 3'UTR (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- TMEM183A | c.*1446_*1447del | 3'UTR (DEL) | VAF 4/47 reads (9%) | catalogued as rs1241695825; called by pindel, varscan2*
- TRPV6 | c.883-139T>G | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- TSLP | c.*1883G>T | 3'UTR (SNP) | VAF 32/127 reads (25%) | catalogued as rs960263109; called by muse, mutect2, varscan2
- UNC5C | c.*5486A>G | 3'UTR (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- UNK | c.491+55G>A | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- VMP1 | c.*1324C>G | 3'UTR (SNP) | VAF 68/173 reads (39%) | called by muse, mutect2, varscan2
- WTAP | c.452+983T>A | Intron (SNP) | VAF 159/342 reads (46%) | called by muse, mutect2, varscan2
- YTHDF1 | c.-206T>C | 5'UTR (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2
- ZNF418 | c.-81+208G>A | Intron (SNP) | VAF 25/42 reads (60%) | called by muse, mutect2, varscan2
- ZNF528 | c.*1369C>T | 3'UTR (SNP) | VAF 28/53 reads (53%) | called by muse, varscan2
